Somatic mutation profile of tumor specimen TCGA-17-Z054-01A (aliquot TCGA-17-Z054-01A-01W-0747-08) from TCGA case TCGA-17-Z054, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z054-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce82f575-1f44-4d65-9d54-a1844d282752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z054-11A (Solid Tissue Normal), aliquot TCGA-17-Z054-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9fbafb-890f-455c-8178-6e089f108b81

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1064796687, COSV61578151; ClinVar: uncertain significance; called by muse, mutect2
- HS3ST1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs370737240, COSV50027385; called by muse, mutect2, varscan2
- RAG1 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- TTC37 | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
